Somatic mutation profile of tumor specimen MP2PRT-PAVSGZ-TMP1-A (aliquot MP2PRT-PAVSGZ-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVSGZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,556 days).
Specimen MP2PRT-PAVSGZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fc7d09d-fca7-42ea-ab9a-ffe71c9d451d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSGZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSGZ-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f3005cb-4a6c-4f68-8aff-6838b697a6c8

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT1 | c.254_256del p.E85del | In Frame Del (DEL) | VAF 32/188 reads (17%) | catalogued as rs866364527; called by pindel, varscan2
- GPATCH2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 67/389 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775087701, COSV65131237; called by muse, mutect2, varscan2
- INPP5F | c.2353A>C p.N785H | Missense Mutation (SNP) | VAF 12/367 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1297484703; called by muse, mutect2
- NR3C2 | c.1680G>A p.W560* | Nonsense Mutation (SNP) | VAF 26/363 reads (7%) | catalogued as rs1553942744; called by muse, mutect2
- PBX4 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs753559018; called by muse, mutect2, varscan2
- SIN3A | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64584735; called by muse, mutect2
- VAV2 | c.2545A>G p.I849V (on ENST00000371850 / NM_001134398.2; = p.I810V on NM_003371.4) | Missense Mutation (SNP) | VAF 34/698 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.986); catalogued as rs765980821; called by muse, mutect2
- GJD2 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 30/752 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- IKZF1 | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 289/668 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM41A | c.40T>C p.C14R | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- TNS4 | c.1802T>C p.V601A | Missense Mutation (SNP) | VAF 52/697 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); called by muse, mutect2
- ABCC8 | c.2304C>T p.P768= | Silent (SNP) | VAF 75/538 reads (14%) | catalogued as rs199541853; called by muse, mutect2
- DCAF13 | c.201T>C p.D67= | Silent (SNP) | VAF 86/479 reads (18%) | called by muse, mutect2, varscan2
- DNAH6 | c.11223A>C p.A3741= | Silent (SNP) | VAF 25/284 reads (9%) | catalogued as rs756263628; called by muse, mutect2
- GPR3 | c.207T>C p.P69= | Silent (SNP) | VAF 38/936 reads (4%) | called by muse, mutect2
- LGI4 | c.558G>A p.A186= | Silent (SNP) | VAF 31/1039 reads (3%) | catalogued as rs1307061652; called by muse, mutect2
- SPTBN5 | c.2466T>C p.S822= | Silent (SNP) | VAF 54/345 reads (16%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.1319-6259T>C | Intron (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
